Somatic mutation profile of tumor specimen TCGA-DJ-A3VI-01A (aliquot TCGA-DJ-A3VI-01A-11D-A23M-08) from TCGA case TCGA-DJ-A3VI, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 52.2 years (19,053 days).
Specimen TCGA-DJ-A3VI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 868c3049-8c1a-4416-a0b8-1e0c17c3c5f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A3VI-10A (Blood Derived Normal), aliquot TCGA-DJ-A3VI-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/550ab88c-0d53-4752-b4f0-3639e484ff52

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, Splice Site 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CCDC136 | c.2448G>C p.K816N | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as COSV99922874; called by muse, mutect2
- DNAJC13 | c.5185A>G p.M1729V | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs1234648546, COSV99607636; called by muse, mutect2, varscan2
- EBAG9 | c.247C>G p.Q83E | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV100520846; called by muse, mutect2
- HTR3B | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52747982, COSV99492122; called by muse, mutect2, varscan2
- MMP7 | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52773180; called by muse, mutect2
- MUC20 | c.1796C>G p.P599R | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.099); catalogued as COSV100291328; called by muse, mutect2, varscan2
- NBEA | c.5787T>A p.C1929* | Nonsense Mutation (SNP) | VAF 102/235 reads (43%) | catalogued as COSV100082185; called by muse, mutect2, varscan2
- PIH1D2 | c.461G>C p.R154T | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99735511; called by muse, mutect2
- RET | c.2833G>A p.V945M | Missense Mutation (SNP) | VAF 84/194 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs587780811, COSV60694266; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SOS2 | c.1622C>T p.S541F | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.615); catalogued as COSV99366412; called by muse, mutect2, varscan2
- TMEM132D | c.1450G>C p.D484H | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV67162092; called by muse, mutect2, varscan2
- TNR | c.2855-1G>A p.X952_splice | Splice Site (SNP) | VAF 18/52 reads (35%) | catalogued as COSV99690472; called by muse, mutect2, varscan2
- TWNK | c.614T>G p.V205G | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV99271716, COSV99272816; called by muse, mutect2, varscan2
- ZIC2 | c.707A>G p.H236R | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs370011753; called by muse, varscan2
- FGGY | c.588T>C p.Y196= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as rs780617931, COSV100365309; called by muse, mutect2, varscan2
- NECAP1 | c.351C>T p.F117= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs1316512759, COSV60250088; called by muse, mutect2, varscan2
- YPEL3 | c.168C>T p.N56= (on ENST00000398838 / NM_001145524.2; = p.N94= on NM_031477.5) | Silent (SNP) | VAF 39/88 reads (44%) | catalogued as rs987636642, COSV54221068, COSV54222477; called by muse, mutect2, varscan2
- ZFP64 | c.39G>C p.S13= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs139412794; called by muse, varscan2
- ABCA12 | c.986-24C>T | Intron (SNP) | VAF 5/64 reads (8%) | catalogued as COSV99790921; called by muse, mutect2
